Gene-level copy-number profile of tumor specimen TCGA-DI-A2QT-01A from TCGA case TCGA-DI-A2QT, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 51.6 years (18,835 days).
Specimen TCGA-DI-A2QT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.22b4f846-1d1e-421c-bbae-0ab9e6a67275.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DI-A2QT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/dd961215-d543-4153-8837-6060a116a40f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 942; copy number 2: 14,841; copy number 3: 36,358; copy number 4: 4,917; copy number 5: 1,001; copy number 6: 834; copy number 7: 335; copy number 8: 16; copy number 9: 76; copy number 10: 99; copy number 11: 8; copy number 13: 23; copy number 14: 120; copy number 17: 37; copy number 18: 33; copy number 20: 118; copy number 23: 26; copy number 24: 30.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DI-A2QT-01A-12D-A19X-01): tumor purity 0.86, ploidy 2.96, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:8,858,127–9,091,245, 3 genes: PTPRD-AS1, AL596451.1, RPS26P3.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 921 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:41,426,655–43,452,912, 67 genes, copy number 7 (broad region; genes not listed).
- chr8:49,496,763–62,249,879, 177 genes, copy number 7–10 (broad region; genes not listed).
- chr8:63,013,068–73,063,061, 154 genes, copy number 7–10 (broad region; genes not listed).
- chr8:73,083,787–73,085,879, 1 gene, copy number 9 (within-gene range 6–9): AC100823.1.
- chr8:125,648,327–126,008,930, 1 gene, copy number 14 (within-gene range 2–14): AC016074.2.
- chr8:125,859,721–133,963,259, 111 genes, copy number 9–20 (broad region; genes not listed).
- chr12:37,575,587–40,570,832, 37 genes, copy number 7–24 (within-gene range 6–24): ZNF970P, AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1.
- chr12:43,155,315–46,876,784, 49 genes, copy number 8–18 (within-gene range 3–18): LINC02461, ADAMTS20, AC090525.1, AC090525.2, AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1, TMEM117, ZNF75BP, AC025030.2, AC025030.1, AC025253.1, AC025253.2, NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, AC009248.3, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1, AC079950.1, U6, AC008124.1, ARID2, AC009464.1, RN7SL246P, KNOP1P2, SCAF11, AC084878.1, SLC38A1, AC025031.3, SLC38A2, AC025031.2, AC008014.1, AC025031.1, AC025031.4, AC025031.5, AC008035.1, OR7A19P, MARK3P1.
- chr17:30,897,336–32,945,106, 92 genes, copy number 9–17 (broad region; genes not listed).
- chr17:36,534,987–40,195,656, 140 genes, copy number 11–23 (broad region; genes not listed).
- chr18:35,841,759–42,691,422, 57 genes, copy number 7: NRBF2P1, MIR187, MIR3929, AC118757.1, AC091060.1, C18orf21, RPRD1A, SLC39A6, ELP2, AC023043.1, MOCOS, AC023043.4, AC023043.2, AC023043.3, FHOD3, AC055840.1, TPGS2, KIAA1328, AC016493.1, AC015961.1, CELF4, AC015961.2, AC090386.1, AC090386.2, AC129908.1, AC009899.1, MIR4318, RPL12P40, AC108452.1, AC100781.1, RN7SKP182, RNU6-706P, MIR924HG, AC011139.1, RPL7AP66, MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P, LINC01901, LINC01902, AC011266.1, LINC01477, RPL17P45, AC068688.1, AC079052.1, KC6, NPM1P1, AC011225.1, PIK3C3, AC087683.2, AC087683.1, AC087683.3, LINC00907, RNA5SP454, AC084335.1.
- chr18:45,571,406–47,102,243, 35 genes, copy number 7 (within-gene range 4–7): AC091151.7, AC091151.1, AC023421.1, AC023421.2, SLC14A1, AC087685.1, SIGLEC15, EPG5, PSTPIP2, RN7SKP26, AC012569.1, RNY4P37, ATP5F1A, HAUS1, RNU6-1278P, C18orf25, RNF165, AC015959.1, AC018931.1, LOXHD1, ST8SIA5, AC090311.1, AC090241.2, AC090241.3, PIAS2, AC090241.1, AC090373.1, KATNAL2, ELOA3D, ELOA3C, ELOA3B, ELOA3, ELOA2, AC012254.5, AC012254.1.

Autosomal genes at a single copy (total copy number 1): 942. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
